CCDI case PBCTTG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/9d3af4f7-020d-4ea2-92e3-8ebeb2d7246e

Demographics
Sex at birth: male.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 7.5 years (2,746 days).

Biospecimens (2 samples)
- Sample 0DZK5E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DZK5G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
